Somatic mutation profile of tumor specimen BA2759D (aliquot aq-BA2759D) from BEATAML1.0 case 2243, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.3 years (26,780 days).
Specimen BA2759D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6613e87-2a7f-4f44-bfa8-d8764e7f776b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2466D (Solid Tissue Normal), aliquot aq-BA2466D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13720f2b-7978-4459-b07f-f77b8934a4b6

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACMSD | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748480525; called by muse, mutect2, varscan2
- TAF4 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- TMEM94 | c.2710C>A p.H904N | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.154); called by muse, mutect2
- CSDC2 | c.258C>T p.T86= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as rs1412022403; called by muse, mutect2
